TCGA case TCGA-61-2109 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dc5a6ce7-01e5-408d-812e-e3e0ddc1cde5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Dead; Days to death: 629 days (1.7 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 40.8 years (14,900 days); Year of diagnosis: 1999; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: >20 mm; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 253 days; Number of cycles: 10; Treatment dose: 8,910 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 253 days; Number of cycles: 10; Treatment dose: 3,125 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 486 days (1.3 years); Days to treatment end: 601 days (1.6 years); Number of cycles: 5; Treatment dose: 325 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 486 days (1.3 years); Days to treatment end: 601 days (1.6 years); Number of cycles: 5; Treatment dose: 9,060 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 42.1 years (15,365 days); Days to diagnosis: 465 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 465 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 465 days (1.3 years); Evidence of recurrence type: Positive Biomarker(s).
- Days to follow up: 629 days (1.7 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-61-2109-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 0.8; Shortest dimension: 0.2.
  Slide TCGA-61-2109-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 95; Percent normal cells: 13; Percent necrosis: 7; Percent stromal cells: 5.
  Slide TCGA-61-2109-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 97; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-61-2109-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Gemzar.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 629 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 629 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 465 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-61-2109-01A-01D-0663-01): tumor purity 0.91, ploidy 1.91, whole-genome doublings 0.
